Somatic mutation profile of tumor specimen TCGA-12-1093-01A (aliquot TCGA-12-1093-01A-01W-0611-08) from TCGA case TCGA-12-1093, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.5 years (24,297 days).
Specimen TCGA-12-1093-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05b211f4-8a96-4ea4-9924-fa3c9cde0c46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1093-10A (Blood Derived Normal), aliquot TCGA-12-1093-10A-01W-0611-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f05dd6d7-ba10-407e-81dd-59ab5f36346a

The open-access MAF lists 68 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 15, Nonsense Mutation 4, RNA 1, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201942473, HM971622, COSV66380532; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTPRT | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 18/122 reads (15%) | hotspot (GDC flag); catalogued as COSV61965733, COSV62024591; called by mutect2, varscan2
- TSC1 | c.737+2T>C p.X246_splice | Splice Site (SNP) | VAF 14/107 reads (13%) | catalogued as rs1564497308, COSV100051844; ClinVar: likely pathogenic; called by muse, varscan2
- ADAMTS16 | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV99941326; called by muse, mutect2, varscan2
- AKR1C4 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99578718; called by muse, mutect2
- ARFGEF2 | c.2999A>G p.E1000G | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100904265; called by muse, mutect2
- BIRC6 | c.1103T>G p.L368W | Missense Mutation (SNP) | VAF 78/739 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101428323; called by muse, mutect2, varscan2
- BIRC6 | c.13297G>A p.V4433I | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.421); catalogued as COSV101428324; called by muse, mutect2, varscan2
- CACNA1D | c.3223C>T p.R1075W (on ENST00000350061 / NM_001128840.3; = p.R1095W on NM_000720.4) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777765883, COSV99856641; called by muse, mutect2, varscan2
- CADM1 | c.951C>A p.N317K | Missense Mutation (SNP) | VAF 52/1338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100522752; called by muse, mutect2
- CALR3 | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 127/282 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV54170770, COSV99522200; called by muse, mutect2, varscan2
- CFAP61 | c.3088C>T p.R1030W | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs1285111032, COSV99844980; called by muse, mutect2
- CIITA | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as rs749736732, COSV100161983; called by muse, mutect2, varscan2
- DIS3L | c.385C>T p.R129W (on ENST00000319212 / NM_001143688.3; = p.R46W on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756381525, COSV100055254; called by muse, mutect2, varscan2
- DUOX2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750288898, COSV101199631, COSV101199779; called by muse, mutect2, varscan2
- FLT3 | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 69/366 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV99608850; called by muse, mutect2, varscan2
- FOXJ3 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.97); catalogued as rs1357072643, COSV100691831; called by muse, mutect2
- GBP4 | c.491C>A p.A164E | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100864390; called by muse, mutect2
- IL6R | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.024); catalogued as COSV100690852; called by muse, mutect2, varscan2
- KPNA5 | c.1087G>A p.V363I | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100706247; called by muse, mutect2
- KRIT1 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.299); catalogued as COSV100388765; called by muse, mutect2
- LATS1 | c.3104A>C p.D1035A | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99486056; called by muse, mutect2
- LBP | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.106); catalogued as rs748163427, COSV99460895; called by muse, mutect2
- MCHR2 | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV56004558, COSV99912040; called by muse, mutect2, varscan2
- MOGS | c.1541C>T p.T514I | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99270356; called by muse, mutect2, varscan2
- MS4A5 | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100280966, COSV100281011; called by muse, mutect2
- MSH6 | c.2431C>G p.L811V | Missense Mutation (SNP) | VAF 17/357 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV99316026; called by muse, mutect2
- NBEA | c.5178G>T p.L1726F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.979); catalogued as COSV100080490; called by muse, mutect2, varscan2
- NLRP8 | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.071); catalogued as rs1445549378, COSV99404892; called by muse, mutect2, varscan2
- NOS1 | c.1171A>C p.K391Q | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100500665; called by muse, mutect2, varscan2
- OR52E8 | c.802C>G p.R268G | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV101190402, COSV66207529; called by muse, mutect2, varscan2
- P2RY10 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 133/1037 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50682005, COSV50686293; called by muse, mutect2, varscan2
- POU2F1 | c.2015C>A p.T672N (on ENST00000541643 / NM_001365848.1; = p.T695N on NM_002697.4) | Missense Mutation (SNP) | VAF 13/230 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV99611189; called by muse, mutect2
- RASSF8 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs764192034, COSV99280831; called by muse, mutect2
- RORA | c.1165G>A p.D389N (on ENST00000335670 / NM_134261.3; = p.D414N on NM_002943.3) | Missense Mutation (SNP) | VAF 86/455 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs202239576, COSV99832702; called by muse, varscan2
- RPP14 | c.137C>A p.S46* | Nonsense Mutation (SNP) | VAF 43/297 reads (14%) | catalogued as COSV55906620, COSV99916694; called by muse, mutect2, varscan2
- SCN11A | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776207910, COSV56574685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPIND1 | c.1055dup p.I353Hfs*67 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as rs1569029107; called by pindel, varscan2
- SH3BP5 | c.166A>G p.T56A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV99508306; called by muse, varscan2
- SPECC1 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as COSV54952290; called by muse, mutect2, varscan2
- TACO1 | c.684C>A p.N228K | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.087); catalogued as COSV99366494; called by muse, mutect2
- TGFB3 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99472543; called by muse, mutect2
- TIPARP | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148252230; called by muse, mutect2
- TTN | c.53897G>T p.G17966V (on ENST00000591111; = p.G10542V on NM_003319.4) | Missense Mutation (SNP) | VAF 43/714 reads (6%) | PolyPhen probably damaging (1); catalogued as COSV100614261; called by muse, mutect2
- UNC79 | c.2227G>T p.D743Y (on ENST00000393151 / NM_001346218.2; = p.D566Y on NM_020818.5) | Missense Mutation (SNP) | VAF 58/1326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99827987; called by muse, mutect2
- WDR59 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as COSV100049358; called by muse, mutect2
- XPOT | c.1868C>A p.P623Q | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100225549, COSV60344901; called by muse, mutect2
- ZCCHC4 | c.1132A>G p.R378G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV100255264; called by muse, mutect2, varscan2
- ZNF836 | c.2213C>T p.T738M | Missense Mutation (SNP) | VAF 54/411 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.324); catalogued as rs559112614, COSV59084519; called by muse, mutect2, varscan2
- AREG | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 125/2139 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.172); called by muse, mutect2
- PTEN | c.717del p.M239Ifs*17 | Frame Shift Del (DEL) | VAF 130/883 reads (15%) | called by mutect2, pindel, varscan2
- BCKDHA | c.25A>C p.R9= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99524591; called by muse, mutect2, varscan2
- CPQ | c.504G>A p.G168= | Silent (SNP) | VAF 21/342 reads (6%) | catalogued as COSV99612361; called by muse, mutect2
- ENDOD1 | c.921C>T p.S307= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs1399505498, COSV53588456; called by muse, mutect2
- HRC | c.399G>A p.G133= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV99417951; called by muse, mutect2, varscan2
- IMPG1 | c.1380T>A p.T460= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as COSV100886405; called by muse, mutect2, varscan2
- OR4K5 | c.648C>T p.S216= | Silent (SNP) | VAF 46/498 reads (9%) | catalogued as COSV100262398; called by muse, mutect2
- PHKG1 | c.711G>T p.L237= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV99305128; called by muse, mutect2
- POLK | c.1830G>A p.L610= | Silent (SNP) | VAF 13/394 reads (3%) | catalogued as COSV99605962; called by muse, mutect2
- SALL2 | c.735C>A p.I245= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV100444379; called by muse, varscan2
- SLC27A2 | c.756C>T p.S252= | Silent (SNP) | VAF 53/244 reads (22%) | catalogued as rs529162625, COSV99982847; called by muse, mutect2, varscan2
- SUPT4H1 | c.204C>T p.D68= | Silent (SNP) | VAF 43/228 reads (19%) | catalogued as COSV56643333, COSV99842775; called by muse, mutect2, varscan2
- TAOK1 | c.2604G>A p.L868= | Silent (SNP) | VAF 17/395 reads (4%) | called by muse, mutect2
- TCHH | c.5130C>G p.L1710= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as rs1442908902, COSV100915122; called by muse, mutect2, varscan2
- TNFRSF10B | c.1089C>T p.L363= | Silent (SNP) | VAF 146/423 reads (35%) | catalogued as COSV99310987; called by muse, mutect2, varscan2
- ZNF518B | c.2631G>A p.G877= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100456720; called by muse, varscan2
- RRM2 | n.627G>A | RNA (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
